Somatic mutation profile of tumor specimen SM-JU345 (aliquot 7316UP-1352) from CPTAC case C524103, project CPTAC-3 (Other and unspecified urinary organs — Nevi and Melanomas). Sex at birth: female; Vital status: Dead; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Urethra.
Specimen SM-JU345: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Cerebrum; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e542b271-c0eb-4239-9cb8-ed163e9453d1.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105274 (Blood Derived Normal), aliquot 7316UP-1302-1105274; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6b149a4d-cf3f-47a6-a066-e63803e01c04

The open-access MAF lists 48 somatic variants for this specimen: 33 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 30, Silent 13, Intron 2, Nonsense Mutation 2, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.721T>A p.S241T | Missense Mutation (SNP) | VAF 41/276 reads (15%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as CD984149, CM942121, COSV52670786, COSV52675302, COSV53004514; called by muse, mutect2, varscan2
- ALOX5 | c.805C>T p.R269W | Missense Mutation (SNP) | VAF 32/183 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs778418203; called by muse, mutect2, varscan2
- CRISPLD2 | c.1330G>A p.V444M | Missense Mutation (SNP) | VAF 18/301 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as rs760319660; called by muse, mutect2
- DOCK6 | c.2397C>A p.N799K | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.926); catalogued as COSV52948752; called by muse, mutect2, varscan2
- DSCAM | c.1045C>T p.R349C | Missense Mutation (SNP) | VAF 48/369 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs1227425619, COSV68021037; called by muse, mutect2, varscan2
- FRAS1 | c.811C>A p.H271N | Missense Mutation (SNP) | VAF 53/355 reads (15%) | SIFT tolerated (0.46); PolyPhen benign (0.158); catalogued as COSV53598598; called by muse, mutect2, varscan2
- GABRB2 | c.1358G>A p.R453Q (on ENST00000274547; = p.R415Q on NM_000813.3) | Missense Mutation (SNP) | VAF 30/290 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.951); catalogued as rs371728438; called by muse, mutect2, varscan2
- GPT2 | c.1165G>A p.V389M | Missense Mutation (SNP) | VAF 20/174 reads (11%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.995); catalogued as rs143451663; called by muse, mutect2, varscan2
- GRIN2B | c.3169C>T p.R1057C | Missense Mutation (SNP) | VAF 62/468 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as rs761084398; called by muse, mutect2, varscan2
- LLGL1 | c.265C>T p.R89C | Missense Mutation (SNP) | VAF 21/220 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); catalogued as rs775418941, COSV57496026; called by muse, mutect2
- NBAS | c.4975C>T p.R1659W | Missense Mutation (SNP) | VAF 56/354 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs963935830; called by muse, mutect2, varscan2
- NEK10 | c.1718C>G p.S573C | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.866); catalogued as rs1264897408; called by muse, mutect2, varscan2
- NT5DC3 | c.340C>A p.L114I | Missense Mutation (SNP) | VAF 14/170 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.919); catalogued as COSV67322908; called by muse, mutect2
- OR6Y1 | c.775A>G p.M259V | Missense Mutation (SNP) | VAF 27/188 reads (14%) | SIFT deleterious (0.05); PolyPhen benign (0); catalogued as rs909829305; called by muse, mutect2, varscan2
- REG3G | c.262G>A p.V88M | Missense Mutation (SNP) | VAF 22/264 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.514); catalogued as rs779615598, COSV55449323, COSV55450779; called by muse, mutect2
- ROBO3 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as rs373820994; called by muse, mutect2
- SYT4 | c.127T>C p.S43P | Missense Mutation (SNP) | VAF 24/173 reads (14%) | SIFT tolerated (0.23); PolyPhen benign (0.031); catalogued as COSV54904546; called by muse, mutect2, varscan2
- TBC1D22A | c.472G>A p.D158N | Missense Mutation (SNP) | VAF 21/181 reads (12%) | SIFT tolerated (0.46); PolyPhen benign (0.001); catalogued as rs1267287718; called by muse, mutect2, varscan2
- ZNF718 | c.678C>G p.F226L | Missense Mutation (SNP) | VAF 22/122 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as COSV101210245; called by muse, varscan2
- ATRX | c.3271A>T p.K1091* | Nonsense Mutation (SNP) | VAF 27/418 reads (6%) | called by muse, mutect2
- CACNA1I | c.1105G>A p.A369T | Missense Mutation (SNP) | VAF 20/258 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- COL4A1 | c.4865G>A p.C1622Y | Missense Mutation (SNP) | VAF 47/513 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2
- FMN2 | c.1616-1G>T p.X539_splice | Splice Site (SNP) | VAF 15/93 reads (16%) | called by mutect2, varscan2
- NEB | c.11696T>G p.I3899S | Missense Mutation (SNP) | VAF 22/202 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.772); called by muse, mutect2, varscan2
- ORC1 | c.1901A>G p.Y634C | Missense Mutation (SNP) | VAF 52/418 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PGAP2 | c.483C>G p.C161W (on ENST00000463452 / NM_001346398.2; = p.C222W on NM_014489.4) | Missense Mutation (SNP) | VAF 23/180 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- RAD54L2 | c.3004C>T p.P1002S | Missense Mutation (SNP) | VAF 8/106 reads (8%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.549); called by muse, mutect2
- SCUBE1 | c.703C>A p.H235N | Missense Mutation (SNP) | VAF 21/180 reads (12%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.947); called by muse, mutect2, varscan2
- SPATA31D3 | c.290A>C p.K97T | Missense Mutation (SNP) | VAF 34/332 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.813); called by muse, mutect2
- TEPSIN | c.832T>A p.C278S | Missense Mutation (SNP) | VAF 35/134 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- TRIOBP | c.5250G>A p.W1750* | Nonsense Mutation (SNP) | VAF 24/462 reads (5%) | called by muse, mutect2
- TRPC7 | c.1555C>A p.P519T | Missense Mutation (SNP) | VAF 26/198 reads (13%) | SIFT tolerated (0.29); PolyPhen benign (0.158); called by mutect2, varscan2
- ZNF91 | c.2231G>A p.C744Y | Missense Mutation (SNP) | VAF 29/247 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); called by muse, mutect2, varscan2
- AKAP3 | c.2557C>T p.L853= | Silent (SNP) | VAF 13/132 reads (10%) | catalogued as rs780846438; called by muse, mutect2
- CEP250 | c.5244C>T p.L1748= | Silent (SNP) | VAF 18/184 reads (10%) | catalogued as rs1296536087; called by muse, mutect2
- DACT2 | c.1542G>A p.P514= | Silent (SNP) | VAF 20/249 reads (8%) | catalogued as rs890309903; called by muse, mutect2
- EFCAB14 | c.108T>G p.P36= | Silent (SNP) | VAF 21/257 reads (8%) | called by muse, mutect2
- FAM170B | c.768G>A p.E256= | Silent (SNP) | VAF 36/186 reads (19%) | catalogued as rs1358578431; called by muse, mutect2, varscan2
- GCN1 | c.7848T>A p.I2616= | Silent (SNP) | VAF 38/257 reads (15%) | called by muse, mutect2, varscan2
- HACE1 | c.2622C>T p.S874= | Silent (SNP) | VAF 27/420 reads (6%) | catalogued as rs142237732; called by muse, mutect2
- MAP4K2 | c.1764G>C p.L588= | Silent (SNP) | VAF 27/184 reads (15%) | called by muse, mutect2, varscan2
- MYO15A | c.2352G>A p.P784= | Silent (SNP) | VAF 70/527 reads (13%) | catalogued as rs748006735; called by muse, mutect2, varscan2
- PDCD7 | c.480G>A p.P160= | Silent (SNP) | VAF 14/134 reads (10%) | called by muse, mutect2, varscan2
- XKR4 | c.1488C>T p.F496= | Silent (SNP) | VAF 16/382 reads (4%) | called by muse, mutect2
- XKR4 | c.1782C>T p.V594= | Silent (SNP) | VAF 22/278 reads (8%) | called by muse, mutect2
- ZBTB10 | c.1269C>T p.F423= | Silent (SNP) | VAF 14/356 reads (4%) | called by muse, mutect2
- CABIN1 | c.4117+57dup | Intron (INS) | VAF 34/269 reads (13%) | catalogued as rs766082760; called by mutect2, varscan2
- SMARCC1 | c.1899+20T>C | Intron (SNP) | VAF 24/186 reads (13%) | catalogued as rs1029053019; called by muse, mutect2, varscan2
